Gene-level copy-number profile of tumor specimen ALCH-B28T-TTP1-A from ALCHEMIST case ALCH-B28T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,296 days).
Specimen ALCH-B28T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d5e556d7-ebdf-49ca-9dac-93042b183064.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B28T-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/4b02dffb-b2c5-49e8-a039-4b15353c2e35

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 10,122; copy number 2: 46,871; copy number 3: 1,107; copy number 4: 205; copy number 6: 2; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,080,066–36,125,222, 4 genes: AL138787.1, TEKT2, ADPRS, COL8A2.
- chr1:120,354,987–120,355,148, 1 gene: U1.
- chr2:11,155,198–11,178,870, 1 gene: SLC66A3.
- chr3:48,856,926–48,898,904, 1 gene: SLC25A20.
- chr4:40,020,240–40,021,517, 1 gene: KRT18P25.
- chr5:40,759,379–40,835,222, 4 genes (within-gene range 0–1): PRKAA1, AC008810.1, RPL37, SNORD72.
- chr6:110,982,015–111,047,521, 2 genes: RPF2, GSTM2P1.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr9:77,040,416–77,040,673, 1 gene: ATP5MFP3.
- chr9:136,712,572–136,724,742, 1 gene (within-gene range 0–1): DIPK1B.
- chr9:138,177,426–138,179,774, 1 gene: AL591424.2.
- chr10:71,508,153–71,511,873, 1 gene (within-gene range 0–1): CDH23-AS1.
- chr10:93,059,663–93,077,885, 5 genes: AL358613.1, CYP26C1, AL358613.3, AL358613.2, CYP26A1.
- chr10:133,355,158–133,373,354, 3 genes: FUOM, ECHS1, MIR3944.
- chr11:694,438–727,727, 3 genes (within-gene range 0–5): EPS8L2, TMEM80, AP006621.4.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr12:48,829,756–48,852,842, 1 gene: DDX23.
- chr15:25,182,385–25,238,067, 31 genes (within-gene range 0–1): SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37.
- chr16:1,889,114–1,890,434, 1 gene: LINC02124.
- chr16:4,556,490–4,600,714, 3 genes: C16orf96, AC023830.2, SUB1P3.
- chr16:85,697,335–85,697,868, 1 gene (within-gene range 0–2): AC018695.6.
- chr17:404,468–414,023, 1 gene (within-gene range 0–1): AC141424.1.
- chr17:67,019,934–67,033,290, 2 genes (within-gene range 0–2): AC005544.1, AC005544.2.
- chr18:50,959,267–50,988,121, 2 genes (within-gene range 0–2): Y_RNA, ELAC1.
- chr19:8,490,056–8,502,640, 1 gene: PRAM1.
- chr20:23,030,863–23,039,241, 2 genes: AL049651.2, SSTR4.
- chr20:64,073,181–64,079,988, 2 genes: RGS19, MIR6813.
- chr22:41,722,043–41,722,131, 1 gene (within-gene range 0–1): RNU6ATAC22P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:112,967–126,123, 2 genes, copy number 10: AC069287.1, CICP23.
- chr11:129,279–186,136, 2 genes, copy number 6 (within-gene range 2–6): AC069287.3, RNU6-447P.

Autosomal genes at a single copy (total copy number 1): 10,119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
